Somatic mutation profile of cancer-model specimen HCM-CSHL-0373-C25-85A (3D Organoid, passage 12; aliquot HCM-CSHL-0373-C25-85A-01D-A79M-36), derived from the primary tumor of HCMI case HCM-CSHL-0373-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3; Age at diagnosis: 71.9 years (26,274 days).
Specimen HCM-CSHL-0373-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 12.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 91b0b08b-023d-4064-b49a-91e5d02fc0ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0373-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0373-C25-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e1d43f6c-2a7b-4368-ad97-dc4f95612996

The open-access MAF lists 60 somatic variants for this specimen: 46 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 11, Nonsense Mutation 3, 3'UTR 2, Splice Region 1, Frame Shift Ins 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DUSP16 | c.1447C>T p.R483* | Nonsense Mutation (SNP) | VAF 229/479 reads (48%) | hotspot (GDC flag); catalogued as COSV53806110; called by muse, mutect2, varscan2
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 206/421 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PYGL | c.2024C>T p.S675L | Missense Mutation (SNP) | VAF 225/230 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs113993986, CM078414; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 234/234 reads (100%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAMTS2 | c.2414C>T p.T805M | Missense Mutation (SNP) | VAF 319/650 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); catalogued as rs370350117; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARID1A | c.6526C>T p.Q2176* | Nonsense Mutation (SNP) | VAF 314/315 reads (100%) | catalogued as COSV61384821; called by muse, mutect2, varscan2
- BCAR1 | c.2222G>A p.R741Q | Missense Mutation (SNP) | VAF 341/694 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs754367401; called by muse, mutect2, varscan2
- CASP2 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 122/122 reads (100%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.769); catalogued as rs775676786, COSV100131025; called by muse, mutect2, varscan2
- CD1D | c.1000G>A p.V334I | Missense Mutation (SNP) | VAF 212/406 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777157013, COSV63808414; called by muse, mutect2, varscan2
- CTNND2 | c.1429G>A p.G477S | Missense Mutation (SNP) | VAF 286/645 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as rs201021638, COSV58918848; called by muse, mutect2, varscan2
- DDX50 | c.1798G>A p.D600N | Missense Mutation (SNP) | VAF 123/281 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV101007301; called by muse, mutect2, varscan2
- FAT3 | c.12542G>A p.R4181H | Missense Mutation (SNP) | VAF 136/393 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.769); catalogued as rs368233172, COSV53170350; called by muse, mutect2, varscan2
- KMT2D | c.13472T>A p.I4491N | Missense Mutation (SNP) | VAF 23/738 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.577); catalogued as rs1298743172, COSV56409393, COSV56497206; called by muse, mutect2
- NLRP5 | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 205/641 reads (32%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs749175273, COSV66762758; called by muse, mutect2, varscan2
- OR2T3 | c.928A>G p.M310V | Missense Mutation (SNP) | VAF 207/962 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs530686348, COSV100613049; called by muse, mutect2
- PBRM1 | c.829A>T p.K277* | Nonsense Mutation (SNP) | VAF 103/103 reads (100%) | catalogued as COSV56260223, COSV56261335; called by muse, mutect2, varscan2
- PDE3A | c.350G>T p.G117V | Missense Mutation (SNP) | VAF 452/920 reads (49%) | SIFT tolerated, low confidence (0.38); PolyPhen possibly damaging (0.898); catalogued as COSV62973060; called by muse, mutect2, varscan2
- PLEKHG3 | c.460C>T p.R154W (on ENST00000394691; = p.R210W on NM_001308147.2) | Missense Mutation (SNP) | VAF 421/422 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs769014906; called by muse, mutect2, varscan2
- SERPINE3 | c.395C>G p.S132C | Missense Mutation (SNP) | VAF 86/596 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs747512948; called by muse, mutect2, varscan2
- SYT3 | c.1516G>A p.V506M | Missense Mutation (SNP) | VAF 184/626 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs376860461; called by muse, mutect2, varscan2
- THBS2 | c.1637G>A p.R546K | Missense Mutation (SNP) | VAF 50/258 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100827979; called by muse, mutect2, varscan2
- UNC5A | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 337/682 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs768440834; called by muse, mutect2, varscan2
- USP6NL | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 402/800 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs767258666; called by muse, mutect2
- ZBTB41 | c.2257G>A p.D753N | Missense Mutation (SNP) | VAF 67/433 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as rs747454532, COSV100962987, COSV66359158; called by muse, mutect2, varscan2
- ACTN3 | c.2642C>A p.A881D | Missense Mutation (SNP) | VAF 39/660 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2
- ATOH1 | c.196G>C p.A66P | Missense Mutation (SNP) | VAF 443/554 reads (80%) | SIFT deleterious (0); PolyPhen benign (0.403); called by muse, varscan2
- BMI1 | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 61/148 reads (41%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRELD1 | c.782T>G p.F261C | Missense Mutation (SNP) | VAF 9/224 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- DHX34 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 171/557 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- EPHA4 | c.1159A>C p.T387P | Missense Mutation (SNP) | VAF 162/518 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- GAD2 | c.975+1_975+3del p.X325_splice | Splice Site (DEL) | VAF 96/215 reads (45%) | called by mutect2, pindel, varscan2
- GOLGA6L2 | c.1841G>A p.G614E | Missense Mutation (SNP) | VAF 343/1394 reads (25%) | SIFT deleterious, low confidence (0.04); called by muse, mutect2, varscan2
- GTF2IRD2B | c.2260G>T p.A754S | Missense Mutation (SNP) | VAF 69/145 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MAGEL2 | c.867T>G p.I289M | Missense Mutation (SNP) | VAF 342/733 reads (47%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- NLRP7 | c.2092C>T p.H698Y (on ENST00000340844 / NM_206828.3; = p.H670Y on NM_139176.3) | Missense Mutation (SNP) | VAF 164/595 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- PCDHGA4 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 238/517 reads (46%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PDZD2 | c.5421dup p.H1808Tfs*2 | Frame Shift Ins (INS) | VAF 177/419 reads (42%) | called by mutect2, pindel, varscan2
- PXDN | c.7A>G p.K3E | Missense Mutation (SNP) | VAF 79/588 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RANBP3L | c.831A>C p.Q277H | Missense Mutation (SNP) | VAF 192/448 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- RIMS1 | c.1375G>T p.A459S | Missense Mutation (SNP) | VAF 28/502 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2
- ROBO4 | c.1561G>A p.D521N | Missense Mutation (SNP) | VAF 62/447 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- RPRM | c.7C>A p.P3T | Missense Mutation (SNP) | VAF 233/479 reads (49%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SF1 | c.815G>T p.S272I | Missense Mutation (SNP) | VAF 87/307 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- SLC12A3 | c.590A>G p.K197R | Missense Mutation (SNP) | VAF 114/327 reads (35%) | SIFT tolerated (0.73); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- TRAV17 | c.200T>C p.I67T | Missense Mutation (SNP) | VAF 26/248 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ZMYM4 | c.2436G>A p.Q812= | Splice Region (SNP) | VAF 7/163 reads (4%) | called by muse, mutect2
- ADAMTS18 | c.3648A>G p.S1216= | Silent (SNP) | VAF 113/237 reads (48%) | called by muse, mutect2, varscan2
- BTN1A1 | c.687G>A p.K229= | Silent (SNP) | VAF 148/194 reads (76%) | catalogued as rs201998297, COSV55070254; called by muse, mutect2, varscan2
- CDH26 | c.1260C>T p.A420= | Silent (SNP) | VAF 141/320 reads (44%) | catalogued as rs1316778719; called by muse, mutect2, varscan2
- CFAP43 | c.645C>A p.P215= | Silent (SNP) | VAF 14/452 reads (3%) | called by muse, mutect2
- DNAJC6 | c.687G>A p.K229= | Silent (SNP) | VAF 59/534 reads (11%) | called by muse, mutect2, varscan2
- GABPB1 | c.174G>A p.L58= | Silent (SNP) | VAF 39/487 reads (8%) | called by muse, mutect2
- LRRIQ3 | c.1609A>C p.R537= | Silent (SNP) | VAF 22/426 reads (5%) | called by muse, mutect2
- SEMA5A | c.1830C>T p.T610= | Silent (SNP) | VAF 79/566 reads (14%) | called by muse, mutect2, varscan2
- TRIM27 | c.303G>A p.E101= | Silent (SNP) | VAF 621/746 reads (83%) | catalogued as rs757487790; called by muse, mutect2, varscan2
- USP31 | c.459C>G p.A153= | Silent (SNP) | VAF 113/535 reads (21%) | catalogued as COSV54850884, COSV54852733; called by muse, mutect2, varscan2
- XKR7 | c.1566C>A p.V522= | Silent (SNP) | VAF 324/672 reads (48%) | called by muse, varscan2
- CYGB | c.*176G>T | 3'UTR (SNP) | VAF 415/420 reads (99%) | called by muse, mutect2, varscan2
- MCTP1 | c.721-63984del | Intron (DEL) | VAF 145/380 reads (38%) | called by mutect2, pindel, varscan2
- SPAG11B | c.*141A>G | 3'UTR (SNP) | VAF 182/881 reads (21%) | called by muse, mutect2, varscan2
